CCDI case PBBYCB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/47beeb1d-14aa-4617-b81f-84b741b1bea2

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Parietal lobe; Age at diagnosis: 16.0 years (5,830 days).

Biospecimens (2 samples)
- Sample 0DKDC0: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DKDDC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
